Somatic mutation profile of tumor specimen TCGA-19-5953-01B (aliquot TCGA-19-5953-01B-12D-1845-08) from TCGA case TCGA-19-5953, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.1 years (21,204 days).
Specimen TCGA-19-5953-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b797fb3-104a-4e02-bb7e-7e47361b6044.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-5953-10A (Blood Derived Normal), aliquot TCGA-19-5953-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3ea7a9f-7859-47bd-8288-04d5915ced86

The open-access MAF lists 55 somatic variants for this specimen: 31 protein-altering or splice-affecting, 23 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 23, Frame Shift Del 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A2 | c.1009G>A p.G337S | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs67865220, CM070788, CM960326, CM970356, CP015771, COSV51956466; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.4600C>T p.R1534* (on ENST00000358273 / NM_001042492.3; = p.R1513* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 23/76 reads (30%) | catalogued as rs760703505, CM941093, COSV62191852; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 27/98 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1114167656, COSV64290343, COSV64290444, COSV64294220; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRF5 | c.3118T>A p.S1040T | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.531); catalogued as COSV51937309; called by muse, mutect2, varscan2
- ANGPTL1 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.426); catalogued as rs746052727, COSV52367292; called by muse, mutect2, varscan2
- ANKLE2 | c.2044G>C p.E682Q | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as COSV61710594; called by muse, mutect2, varscan2
- BOP1 | c.1034G>A p.R345H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs1017931750; called by muse, mutect2, varscan2
- CHRNB4 | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs770932753, COSV55716325; called by muse, mutect2, varscan2
- CPSF6 | c.193G>C p.G65R | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.265); catalogued as COSV57016525; called by muse, mutect2, varscan2
- DNAI4 | c.1660G>A p.V554I | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as rs375562160; called by muse, mutect2, varscan2
- DRD2 | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200148328, COSV60760313; called by muse, mutect2, varscan2
- DSG3 | c.431C>T p.T144M | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs62095186, COSV57128033; called by muse, mutect2, varscan2
- FAM47A | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV60497611; called by muse, mutect2, varscan2
- FAM83H | c.3361C>T p.R1121C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs782236631, COSV62029239; called by muse, mutect2, varscan2
- FAT2 | c.3545T>C p.M1182T | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV55824828; called by muse, mutect2, varscan2
- INTU | c.232C>G p.L78V | Missense Mutation (SNP) | VAF 73/297 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV56540964; called by muse, mutect2, varscan2
- MIB1 | c.670G>A p.G224S | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.354); catalogued as COSV55092625; called by muse, mutect2, varscan2
- MUC17 | c.2978C>T p.T993M | Missense Mutation (SNP) | VAF 137/702 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs768095131, COSV60296106; called by muse, mutect2, varscan2
- NPAP1 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.19); catalogued as rs751230265, COSV61506807; called by muse, mutect2, varscan2
- PCDHGA6 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs1415388106, COSV53989482; called by muse, varscan2
- PCLO | c.9737G>A p.R3246Q | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs757103714, COSV61617375, COSV61626089; called by muse, mutect2, varscan2
- PDE3B | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs761085973, COSV56381786; called by muse, mutect2, varscan2
- SLC5A4 | c.914A>C p.K305T | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56672311; called by muse, mutect2, varscan2
- SLC9A4 | c.1892G>A p.R631H | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs368438401; called by muse, mutect2, varscan2
- SLCO2B1 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs772856687, COSV56937292, COSV56938658; called by muse, mutect2, varscan2
- TMEM132D | c.2050C>T p.P684S | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.082); catalogued as COSV67161129, COSV67161332; called by muse, mutect2, varscan2
- TRIM58 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780979068, COSV100825273, COSV63569231; called by muse, mutect2, varscan2
- WASHC4 | c.651G>T p.W217C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59890896; called by muse, mutect2, varscan2
- WSCD2 | c.505C>A p.L169M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.133); catalogued as COSV54578718; called by muse, mutect2, varscan2
- ZNF711 | c.1537G>A p.G513S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs866850423, COSV52156660, COSV99341213; called by muse, mutect2, varscan2
- SLC22A16 | c.581del p.L194Cfs*4 | Frame Shift Del (DEL) | VAF 21/84 reads (25%) | called by mutect2, pindel, varscan2
- BAHCC1 | c.2757C>T p.L919= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs782672738, COSV57030179; called by muse, mutect2
- BARHL2 | c.156T>C p.C52= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as COSV64981661; called by muse, mutect2
- CHRNB4 | c.486C>T p.F162= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as rs80249872, COSV55717187; called by muse, mutect2, varscan2
- EEFSEC | c.582C>T p.P194= | Silent (SNP) | VAF 43/163 reads (26%) | catalogued as rs780092371, COSV54629109; called by muse, mutect2, varscan2
- FCGR3A | c.195C>T p.S65= | Silent (SNP) | VAF 50/377 reads (13%) | catalogued as COSV63460086; called by muse, varscan2
- FSIP2 | c.17427A>G p.Q5809= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100553560; called by muse, mutect2, varscan2
- GDF3 | c.594C>T p.F198= | Silent (SNP) | VAF 22/116 reads (19%) | catalogued as rs754962446, COSV61712314; called by muse, mutect2, varscan2
- HSD3B1 | c.528C>T p.N176= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs749065451, COSV52491487; called by muse, mutect2, varscan2
- ITGAD | c.3144C>T p.F1048= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs772928919, COSV54931493; called by muse, mutect2, varscan2
- KIAA1614 | c.3318C>T p.L1106= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV62551337; called by muse, mutect2, varscan2
- LARP1 | c.360C>T p.P120= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1208013867, COSV60429217; called by muse, mutect2, varscan2
- MAG | c.1485C>T p.G495= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs754395124, COSV100727522; called by muse, varscan2
- MANEA | c.1122G>A p.R374= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as COSV62590097; called by muse, mutect2, varscan2
- MAP11 | c.1249C>T p.L417= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV57587190; called by muse, mutect2, varscan2
- NYAP2 | c.1137G>A p.S379= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs762429077, COSV56009570; called by mutect2, varscan2
- OR2A25 | c.859C>T p.L287= | Silent (SNP) | VAF 94/527 reads (18%) | catalogued as rs776164670, COSV68717450; called by muse, mutect2, varscan2
- OR5T3 | c.292C>T p.L98= | Silent (SNP) | VAF 53/186 reads (28%) | catalogued as COSV57381755; called by muse, mutect2, varscan2
- PCDHGA3 | c.1476C>T p.T492= | Silent (SNP) | VAF 28/199 reads (14%) | catalogued as rs753266989, COSV53989469; called by muse, mutect2, varscan2
- SHANK2 | c.5289G>A p.S1763= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as rs782033372, COSV53609250; called by muse, mutect2, varscan2
- SHISA2 | c.528G>A p.S176= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs368288149; called by muse, mutect2, varscan2
- SLC39A2 | c.685C>T p.L229= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as rs764485792, COSV53870555; called by muse, mutect2, varscan2
- TINAGL1 | c.807C>T p.G269= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV54698868, COSV54699545; called by muse, mutect2, varscan2
- ZCWPW1 | c.1845G>A p.E615= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV52201320; called by muse, mutect2, varscan2
- KCNU1 | c.2010-16895A>C | Intron (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2
